Somatic mutation profile of tumor specimen TCGA-CM-6674-01A (aliquot TCGA-CM-6674-01A-11D-1835-10) from TCGA case TCGA-CM-6674, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Hepatic flexure of colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 39.3 years (14,368 days).
Specimen TCGA-CM-6674-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2db344ed-d6d8-4814-a449-da6ad88ee946.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6674-10A (Blood Derived Normal), aliquot TCGA-CM-6674-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45c4febf-86db-43bb-a91c-e1764dd8a927

The open-access MAF lists 1,047 somatic variants for this specimen: 794 protein-altering or splice-affecting, 235 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 536, Silent 235, Frame Shift Del 160, Frame Shift Ins 39, Nonsense Mutation 35, In Frame Del 15, Intron 11, Splice Site 6, 3'UTR 4, RNA 2, Splice Region 2, Nonstop Mutation 1.

Variants (750 of 1,047; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1557055316, CM950057, COSV54388017; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP8B1 | c.614dup p.N205Kfs*2 | Frame Shift Ins (INS) | VAF 38/162 reads (23%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- C19orf12 | c.248C>T p.P83L (on ENST00000392278 / NM_001031726.3; = p.P72L on NM_031448.6) | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201987973, CM132606, COSV100080683; ClinVar: pathogenic; called by muse, varscan2
- CACNA1A | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs121908211, CM960237, COSV64192384; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL18A1 | c.3918del p.G1307Dfs*17 (on ENST00000359759 / NM_130444.3; = p.G1072Dfs*17 on NM_030582.4) | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as rs749009747; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KMT2B | c.4622C>T p.A1541V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1568377293, COSV55858441; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 48/178 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRIT1 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as rs777198867, CM022616, COSV60667206; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LGI1 | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064794249, CM102034, COSV65057607; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.793del p.R265Vfs*3 | Frame Shift Del (DEL) | VAF 26/129 reads (20%) | catalogued as rs863225384, CM011411, CM064120, CS105415, COSV51615553, COSV51616044; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PXDN | c.2568del p.C857Afs*5 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs558163499, CD117085; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- SMARCB1 | c.463C>T p.R155* (on ENST00000263121; = p.R201* on NM_003073.5) | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as rs1555877286, CM992975, COSV54093216; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SOX9 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1555629169, COSV55422898; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1231184822, COSV55746451; called by muse, varscan2
- ABCA12 | c.5873C>T p.A1958V (on ENST00000272895 / NM_173076.3; = p.A1640V on NM_015657.3) | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.456); catalogued as COSV55952060; called by muse, mutect2, varscan2
- ABCA12 | c.2258A>G p.H753R (on ENST00000272895 / NM_173076.3; = p.H435R on NM_015657.3) | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.977); catalogued as COSV55952077; called by muse, mutect2, varscan2
- ABCA12 | c.170T>A p.L57H | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55952090; called by muse, mutect2, varscan2
- ABCA7 | c.2614G>A p.V872I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs375032351; called by muse, mutect2, varscan2
- ABCA9 | c.1196T>C p.I399T | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV60621967; called by muse, mutect2, varscan2
- ABCB9 | c.1975C>T p.R659W (on ENST00000280560 / NM_019625.4; = p.R616W on NM_019624.3) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774362505, COSV54890681; called by muse, mutect2, varscan2
- ABL2 | c.3203C>T p.A1068V (on ENST00000502732 / NM_007314.4; = p.A1053V on NM_005158.5) | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated, low confidence (0.53); PolyPhen possibly damaging (0.665); catalogued as COSV61011763; called by muse, mutect2, varscan2
- ABO | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.676); catalogued as rs965109821, COSV101506016; called by muse, mutect2, varscan2
- AC004922.1 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 28/102 reads (27%) | catalogued as COSV99501462; called by muse, mutect2, varscan2
- AC100868.1 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.657); catalogued as COSV51839503, COSV51850408; called by muse, mutect2, varscan2
- ACE | c.818T>C p.L273P | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as COSV99326556; called by muse, varscan2
- ACIN1 | c.1339del p.A447Lfs*19 | Frame Shift Del (DEL) | VAF 30/102 reads (29%) | catalogued as rs879396950, COSV52972585; called by mutect2, pindel, varscan2
- ACO1 | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as COSV59377781; called by muse, mutect2, varscan2
- ACOT4 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs779781837, COSV58335453; called by muse, mutect2, varscan2
- ACVR1B | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV57775575; called by muse, mutect2, varscan2
- ACVR1B | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs757836305, COSV57775597; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM30 | c.844del p.S282Vfs*3 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | catalogued as rs757984494, COSV65561192; called by mutect2, varscan2
- ADAMTS17 | c.1721del p.P575Lfs*13 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | catalogued as rs779966272; called by mutect2, pindel, varscan2
- ADAT1 | c.230G>T p.R77M | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57185600; called by muse, mutect2, varscan2
- ADGRA1 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as COSV66925117; called by muse, mutect2, varscan2
- ADGRB1 | c.1980G>T p.E660D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV60093209; called by muse, mutect2, varscan2
- ADGRL1 | c.689C>T p.T230M (on ENST00000340736 / NM_001008701.3; = p.T225M on NM_014921.5) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs896765574, COSV61563905; called by muse, mutect2, varscan2
- ADGRV1 | c.16640G>A p.R5547H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs200907244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADORA2A | c.832C>A p.H278N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58378144; called by muse, mutect2, varscan2
- ADRA1D | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs538270081, COSV65240389; called by muse, mutect2, varscan2
- AFDN | c.4801C>T p.R1601* | Nonsense Mutation (SNP) | VAF 15/83 reads (18%) | catalogued as COSV60039863; called by muse, mutect2, varscan2
- AHRR | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100328188; called by muse, mutect2, varscan2
- ALDH3A1 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as rs780443108, COSV56734709; called by muse, mutect2, varscan2
- ALOX12 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as rs1401805266, COSV52348961; called by muse, mutect2, varscan2
- ALOX15 | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs760254381, COSV53396518; called by muse, mutect2, varscan2
- ALS2 | c.1609G>T p.G537W | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51885093; called by muse, mutect2, varscan2
- AMBRA1 | c.1592A>T p.Q531L (on ENST00000458649 / NM_001367468.1; = p.Q441L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); catalogued as COSV54050128; called by muse, mutect2, varscan2
- AMPD2 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs202115880, COSV56646782; called by muse, mutect2, varscan2
- ANKRD11 | c.2539G>A p.D847N | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.996); catalogued as rs565590201, COSV56356955; called by muse, mutect2, varscan2
- ANKRD11 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1178134024, COSV99971038; called by muse, mutect2, varscan2
- ANKRD27 | c.2572G>A p.V858M | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs778133400, COSV60129575; called by muse, mutect2, varscan2
- ANKRD34A | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1348584575, COSV60160440; called by muse, mutect2, varscan2
- ANO9 | c.772-3del | Splice Region (DEL) | VAF 13/61 reads (21%) | catalogued as rs535142896; called by mutect2, pindel, varscan2
- AP2A2 | c.170dup p.Y58Vfs*14 | Frame Shift Ins (INS) | VAF 40/164 reads (24%) | catalogued as rs753029866; called by mutect2, varscan2
- AP3D1 | c.2950G>A p.V984I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.237); catalogued as rs367631461; called by muse, mutect2
- AP5Z1 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs769661656, COSV100804291; called by muse, mutect2, varscan2
- APAF1 | c.1805del p.N602Tfs*8 (on ENST00000551964 / NM_181861.2; = p.N591Tfs*8 on NM_001160.3) | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs758129366; called by mutect2, varscan2
- APC | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as rs876660612, COSV57331562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOL2 | c.458T>C p.M153T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs1351974800, COSV50771914; called by muse, mutect2, varscan2
- ARFGEF1 | c.4655dup p.P1553Tfs*7 | Frame Shift Ins (INS) | VAF 12/52 reads (23%) | catalogued as rs774148781; called by mutect2, varscan2
- ARHGAP28 | c.1237G>A p.G413S (on ENST00000383472 / NM_001366230.1; = p.G254S on NM_001010000.3) | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV51633600; called by muse, mutect2, varscan2
- ARHGAP32 | c.4184T>C p.L1395P (on ENST00000310343 / NM_001378025.1; = p.L1046P on NM_014715.4) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100089829; called by muse, mutect2
- ARHGAP32 | c.1345T>G p.Y449D (on ENST00000310343 / NM_001378025.1; = p.Y100D on NM_014715.4) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59844522; called by muse, mutect2, varscan2
- ARHGAP33 | c.779G>A p.G260D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.144); catalogued as COSV99140656; called by muse, mutect2, varscan2
- ARHGAP4 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs782349092, COSV63131139; called by muse, mutect2, varscan2
- ARHGEF18 | c.1957G>A p.G653S (on ENST00000359920 / NM_001130955.2; = p.G549S on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs761507984, COSV60467886; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGEF18 | c.2872C>T p.R958W (on ENST00000359920 / NM_001130955.2; = p.R854W on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs374312353; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as COSV61389445; called by mutect2, varscan2
- ARID1B | c.5428G>T p.G1810W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51652814; called by muse, mutect2, varscan2
- ASPG | c.1075del p.E359Rfs*2 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as COSV101496412; called by mutect2, pindel, varscan2
- ASTN1 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); catalogued as rs750217502, COSV56063949; called by muse, mutect2, varscan2
- ATAD2 | c.1423_1424del p.L475Gfs*8 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | catalogued as rs748411494; called by pindel, varscan2
- ATP13A2 | c.2916_2918del p.T973del | In Frame Del (DEL) | VAF 19/74 reads (26%) | catalogued as rs775654672; called by pindel, varscan2
- ATP1A2 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1219118149, COSV63402758; called by muse, mutect2, varscan2
- ATP5MC1 | c.71C>A p.P24H | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs966582350, COSV100582449; called by muse, mutect2
- ATP7A | c.3470C>T p.S1157L | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0.238); catalogued as COSV58443813; called by muse, mutect2, varscan2
- ATXN1 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs761160445, COSV55210934; called by muse, mutect2, varscan2
- B3GAT1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.48); catalogued as rs746356457, COSV56995655; called by muse, mutect2, varscan2
- BAHCC1 | c.1676del p.G559Afs*75 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs1555653099; called by mutect2, pindel, varscan2
- BAHCC1 | c.6695G>A p.R2232Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.695); catalogued as rs782781834, COSV57024037; called by muse, mutect2, varscan2
- BCL9L | c.1354del p.Q452Sfs*11 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs756382429; called by mutect2, pindel, varscan2
- BCORL1 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs199910278, COSV99501342; called by muse, mutect2, varscan2
- BEND3 | c.1612A>G p.K538E | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.117); catalogued as rs868953855, COSV100944726; called by muse, mutect2, varscan2
- BIN3 | c.338del p.K113Sfs*13 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | catalogued as rs776003776; called by mutect2, pindel, varscan2
- BIRC6 | c.5026G>A p.V1676M | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.747); catalogued as COSV70196758; called by muse, mutect2, varscan2
- BIRC6 | c.12035T>C p.V4012A | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as COSV66042802; called by muse, mutect2, varscan2
- BMP1 | c.2448del p.V817Sfs*52 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as COSV60535319; called by mutect2, pindel, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BNC2 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773045476, COSV66142375; called by muse, mutect2, varscan2
- BRD8 | c.3202G>A p.E1068K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs768962262, COSV54724654; called by muse, mutect2, varscan2
- BTBD11 | c.2954C>T p.P985L (on ENST00000280758 / NM_001018072.2; = p.P522L on NM_001017523.2) | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV55019469; called by muse, mutect2, varscan2
- C11orf58 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.473); catalogued as rs757516929, COSV57178246; called by muse, mutect2, varscan2
- C1GALT1C1L | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs763597084; called by muse, mutect2, varscan2
- C1orf56 | c.828_829del p.Q277Efs*48 | Frame Shift Del (DEL) | VAF 21/104 reads (20%) | catalogued as rs1231480175; called by pindel, varscan2
- C2orf73 | c.326C>A p.P109Q | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV58310295; called by muse, mutect2, varscan2
- C3 | c.2327A>C p.E776A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV99837491; called by mutect2, varscan2
- C5 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs148539497; called by muse, mutect2, varscan2
- C5AR1 | c.926G>A p.G309D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV100754082; called by muse, varscan2
- C7orf31 | c.358del p.S120Vfs*9 | Frame Shift Del (DEL) | VAF 32/157 reads (20%) | catalogued as rs750735753; called by mutect2, varscan2
- CABLES2 | c.1181T>C p.V394A | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as COSV54155981; called by muse, mutect2, varscan2
- CACNA1C | c.3664G>A p.E1222K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV59696532, COSV59703144; called by muse, mutect2, varscan2
- CACNA1H | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs756550215, COSV61985824; called by muse, mutect2, varscan2
- CACNG2 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as rs1169099240, COSV55633030; called by muse, mutect2, varscan2
- CAGE1 | c.811G>A p.A271T (on ENST00000512086; = p.A135T on NM_205864.3) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV57075528; called by muse, mutect2, varscan2
- CALCRL | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144814027; called by muse, mutect2, varscan2
- CAMKK2 | c.1746G>T p.E582D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV100243282; called by muse, mutect2, varscan2
- CAMSAP3 | c.3586G>A p.A1196T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.071); catalogued as rs1393887283, COSV50331606; called by muse, mutect2, varscan2
- CAPN2 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV54334923; called by muse, mutect2, varscan2
- CAPN5 | c.500G>A p.R167H (on ENST00000456580; = p.R127H on NM_004055.5) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.763); catalogued as rs377123751, COSV53686192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASKIN2 | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.7); catalogued as rs760229839, COSV58593602; called by muse, mutect2, varscan2
- CBLL2 | c.516A>C p.Q172H | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.125); catalogued as COSV60368599; called by muse, mutect2, varscan2
- CC2D1B | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as rs560672859, COSV52559258; called by muse, mutect2, varscan2
- CCAR1 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs748256307, COSV56268129, COSV56268161; called by muse, mutect2, varscan2
- CCDC102A | c.802A>G p.K268E | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV50775926; called by muse, mutect2, varscan2
- CCDC136 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.441); catalogued as rs755591957, COSV52797228; called by muse, mutect2, varscan2
- CCDC158 | c.3029G>A p.R1010H | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs375412402; called by muse, mutect2, varscan2
- CCDC6 | c.1348C>T p.Q450* | Nonsense Mutation (SNP) | VAF 54/259 reads (21%) | catalogued as COSV54055380; called by muse, mutect2, varscan2
- CCDC80 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52815530; called by muse, mutect2, varscan2
- CCKAR | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761018926, COSV55160362; called by muse, mutect2, varscan2
- CCKBR | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as rs1385850242, COSV58099513; called by muse, mutect2, varscan2
- CCR1 | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV56122943; called by muse, mutect2
- CD151 | c.533del p.R178Lfs*43 | Frame Shift Del (DEL) | VAF 33/140 reads (24%) | catalogued as CM033595, COSV58989316, COSV58989401; called by mutect2, pindel, varscan2
- CD163 | c.1049G>A p.W350* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV63130495; called by muse, mutect2, varscan2
- CD207 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782242067, COSV69651818; called by muse, mutect2, varscan2
- CDH15 | c.2306G>A p.W769* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99229058; called by mutect2, varscan2
- CDH16 | c.1686del p.K563Sfs*22 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs776664434; called by mutect2, pindel, varscan2
- CDH3 | c.1790A>C p.E597A | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.23); catalogued as COSV99869492; called by muse, mutect2, varscan2
- CDHR3 | c.971G>A p.G324D | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58414913; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1356_1359del p.E454Kfs*11 | Frame Shift Del (DEL) | VAF 22/107 reads (21%) | catalogued as rs1445111778; called by mutect2, pindel, varscan2
- CECR2 | c.1700G>A p.R567Q (on ENST00000342247 / NM_001290047.2; = p.R384Q on NM_001290046.1) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99379449; called by muse, mutect2, varscan2
- CEP162 | c.2176C>T p.R726* | Nonsense Mutation (SNP) | VAF 11/317 reads (3%) | catalogued as rs1413364753, COSV100002366; called by muse, mutect2
- CHEK1 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs761313560, COSV54022462; called by muse, mutect2, varscan2
- CHPF | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV60533939; called by muse, mutect2, varscan2
- CHRFAM7A | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs763039096, COSV100241605; called by mutect2, varscan2
- CHRNB2 | c.570G>T p.E190D | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV63807850; called by muse, mutect2, varscan2
- CIITA | c.1962del p.A656Pfs*30 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | catalogued as COSV60863473; called by pindel, varscan2
- CIT | c.3001C>T p.R1001* | Nonsense Mutation (SNP) | VAF 38/241 reads (16%) | catalogued as COSV55862966; called by muse, mutect2, varscan2
- CKAP5 | c.3103C>T p.R1035* | Nonsense Mutation (SNP) | VAF 22/77 reads (29%) | catalogued as COSV100371633; called by muse, mutect2, varscan2
- CKM | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV53462370; called by muse, mutect2, varscan2
- CLDN11 | c.226+2T>C p.X76_splice | Splice Site (SNP) | VAF 12/59 reads (20%) | catalogued as COSV50355145; called by muse, mutect2, varscan2
- CLDN18 | c.573G>A p.M191I | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV51736115; called by muse, mutect2, varscan2
- CLEC16A | c.2435G>A p.R812H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771251015, COSV99901835; called by muse, mutect2, varscan2
- CLIC1 | c.667T>C p.C223R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV101007579; called by muse, mutect2, varscan2
- CLINT1 | c.905A>G p.Q302R | Missense Mutation (SNP) | VAF 62/260 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.033); catalogued as COSV51622358; called by muse, varscan2
- CNTN5 | c.1129A>G p.K377E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as COSV99682734; called by muse, mutect2, varscan2
- CNTNAP4 | c.2227C>T p.R743W | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs528691365, COSV56669638; called by muse, mutect2, varscan2
- CNTRL | c.2776A>G p.M926V | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as rs764882730, COSV99444314; called by muse, mutect2, varscan2
- CNTROB | c.553G>T p.G185W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100366390; called by muse, mutect2
- COL12A1 | c.7696G>A p.A2566T | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV59391579; called by muse, mutect2, varscan2
- COL12A1 | c.5809G>A p.A1937T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.151); catalogued as rs1562184031, COSV59391588; called by muse, mutect2, varscan2
- COL14A1 | c.4949G>A p.R1650Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); catalogued as rs762064528, COSV52849335; called by muse, mutect2, varscan2
- COL18A1 | c.1922G>A p.R641H (on ENST00000359759 / NM_130444.3; = p.R406H on NM_030582.4) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs201095161; called by muse, mutect2, varscan2
- COL6A3 | c.3287G>A p.R1096H | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs200860322; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.2882G>A p.R961Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs774768218, COSV52109691; called by muse, mutect2, varscan2
- COTL1 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99297256; called by muse, varscan2
- CRAT | c.1690A>G p.M564V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs764993529, COSV100540203; called by mutect2, varscan2
- CRNN | c.1127A>G p.Q376R | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV99664479; called by muse, mutect2, varscan2
- CROCC | c.4717C>T p.R1573W | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1277646247, COSV100978475; called by muse, mutect2, varscan2
- CRYGA | c.476dup p.A160Cfs*29 | Frame Shift Ins (INS) | VAF 12/64 reads (19%) | catalogued as rs762650691; called by mutect2, varscan2
- CSF1R | c.491T>C p.I164T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53830663; called by muse, mutect2, varscan2
- CSMD3 | c.9474T>A p.N3158K (on ENST00000297405 / NM_001363185.1; = p.N2989K on NM_052900.3) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV52126475; called by mutect2, varscan2
- CSMD3 | c.9310G>A p.G3104R (on ENST00000297405 / NM_001363185.1; = p.G2935R on NM_052900.3) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs201521605, COSV52126494; called by muse, mutect2, varscan2
- CSNK1E | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.52); catalogued as rs1437706160, COSV63290499; called by muse, mutect2, varscan2
- CSRNP2 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 32/85 reads (38%) | catalogued as rs1206289307, COSV57333911; called by muse, mutect2, varscan2
- CSRNP3 | c.1645G>A p.G549S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.994); catalogued as COSV100086578; called by muse, mutect2, varscan2
- CTTNBP2 | c.3380G>A p.G1127D | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99355177; called by muse, mutect2, varscan2
- CXXC5 | c.885A>T p.K295N | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56793263; called by muse, mutect2, varscan2
- CYP2A13 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs138089886, COSV57836209; called by muse, mutect2, varscan2
- CYP2D6 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs267608276, COSV62243380; called by muse, mutect2, varscan2
- CYTIP | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as rs770910230, COSV51632699; called by muse, mutect2, varscan2
- DAAM1 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs753130754, COSV62834825; called by muse, mutect2, varscan2
- DAND5 | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57683965; called by muse, mutect2, varscan2
- DAPK1 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs375169492, COSV63785292; called by muse, mutect2, varscan2
- DCHS1 | c.3195G>T p.Q1065H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV55032170; called by muse, varscan2
- DCHS1 | c.3184C>A p.R1062S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV55032184; called by muse, varscan2
- DCX | c.404del p.K135Rfs*16 | Frame Shift Del (DEL) | VAF 20/38 reads (53%) | catalogued as CD087671; called by mutect2, pindel, varscan2
- DDX11 | c.1287C>T p.Y429= | Splice Region (SNP) | VAF 20/88 reads (23%) | catalogued as rs371676005, COSV52501116; called by muse, mutect2, varscan2
- DDX11 | c.2089G>A p.G697S | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as rs748906306, COSV52501136; called by muse, mutect2, varscan2
- DDX17 | c.1301T>C p.L434P | Missense Mutation (SNP) | VAF 75/285 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53251282; called by muse, mutect2, varscan2
- DDX60L | c.4925del p.N1642Mfs*9 | Frame Shift Del (DEL) | VAF 32/156 reads (21%) | catalogued as rs773554787; called by mutect2, varscan2
- DEAF1 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1377730093, COSV100102470; called by muse, mutect2, varscan2
- DECR2 | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54793489; called by muse, mutect2, varscan2
- DEPDC1 | c.494A>C p.H165P | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.081); catalogued as COSV63957762; called by muse, mutect2, varscan2
- DEPDC1 | c.395A>T p.K132I | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV63957767; called by muse, mutect2, varscan2
- DEPTOR | c.393G>T p.K131N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as rs1207356130, COSV53813642; called by muse, mutect2, varscan2
- DERA | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV70773871; called by muse, varscan2
- DGKZ | c.1295C>T p.T432I (on ENST00000454345 / NM_001105540.2; = p.T244I on NM_003646.4) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100551927, COSV58985651; called by muse, mutect2, varscan2
- DHX15 | c.1258T>C p.S420P | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61026033; called by muse, mutect2, varscan2
- DIPK1C | c.976T>C p.C326R | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100679998; called by muse, varscan2
- DIRAS1 | c.592A>G p.M198V | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV60215174; called by muse, mutect2, varscan2
- DISP3 | c.1008dup p.S337Qfs*19 | Frame Shift Ins (INS) | VAF 23/79 reads (29%) | catalogued as rs1254844982; called by mutect2, pindel
- DMWD | c.827C>A p.P276Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52175877, COSV52176234; called by muse, mutect2, varscan2
- DNAH10 | c.11684G>A p.R3895H (on ENST00000409039; = p.R3834H on NM_207437.3) | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759123879, COSV68989674; called by muse, mutect2, varscan2
- DNAH5 | c.7505G>A p.R2502H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54210537; called by mutect2, varscan2
- DNAH7 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.083); catalogued as rs1421924098, COSV56755750; called by muse, mutect2, varscan2
- DNAJC5 | c.128A>G p.H43R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62671109; called by muse, mutect2, varscan2
- DOCK2 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV56938995; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 21/99 reads (21%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOK4 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs755411412, COSV54672040; called by muse, mutect2, varscan2
- DOK7 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as rs151079259; called by muse, mutect2, varscan2
- DPF3 | c.803del p.G268Afs*4 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | catalogued as rs750670452, COSV63503637; called by mutect2, pindel, varscan2
- DPH1 | c.646T>C p.S216P | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as rs769281060, COSV53986278; called by muse, mutect2, varscan2
- DPP6 | c.751G>T p.G251C (on ENST00000377770 / NM_001364500.2; = p.G189C on NM_001936.5) | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1374063766, COSV59602684; called by muse, mutect2, varscan2
- DRD2 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV60755411; called by muse, mutect2, varscan2
- DRG1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 68/309 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV58918177; called by muse, mutect2, varscan2
- DSCAML1 | c.3865T>C p.S1289P (on ENST00000321322; = p.S1229P on NM_020693.4) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs924213274, COSV100357496; called by muse, mutect2, varscan2
- DSCAML1 | c.952C>T p.R318C (on ENST00000321322; = p.R258C on NM_020693.4) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58384642; called by muse, mutect2, varscan2
- DTX3 | c.433del p.L145Cfs*51 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs758962538; called by mutect2, pindel
- DUOX1 | c.2954G>C p.R985T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.03); catalogued as COSV100368635; called by muse, mutect2, varscan2
- DUSP7 | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV99623755; called by muse, mutect2, varscan2
- E4F1 | c.1796G>A p.G599D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV57038019; called by muse, mutect2, varscan2
- EAF2 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.989); catalogued as rs774441301, COSV56543689; called by muse, mutect2, varscan2
- ECI1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs1464649491, COSV57042982; called by muse, mutect2, varscan2
- EDC4 | c.532A>G p.S178G | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV54645412; called by muse, mutect2, varscan2
- ELOVL2 | c.616A>T p.T206S | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61154441; called by muse, mutect2, varscan2
- ELOVL6 | c.272C>G p.T91S | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as COSV56427544; called by muse, mutect2, varscan2
- EPG5 | c.4741A>G p.T1581A | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as COSV99958385; called by muse, mutect2, varscan2
- EPS8L1 | c.1280C>T p.P427L (on ENST00000201647 / NM_133180.3; = p.P300L on NM_017729.3) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs548545431, COSV52380517; called by muse, mutect2, varscan2
- ERAP1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV57085340; called by muse, mutect2, varscan2
- EVPL | c.1458G>T p.Q486H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as COSV56908567; called by muse, mutect2, varscan2
- EXOC3L1 | c.1931C>T p.A644V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV52045438; called by muse, mutect2, varscan2
- EZR | c.179A>T p.K60M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV61452980; called by muse, mutect2, varscan2
- FAM107B | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs763943353, COSV51681273; called by muse, mutect2, varscan2
- FAM151A | c.351dup p.T118Hfs*5 | Frame Shift Ins (INS) | VAF 10/45 reads (22%) | catalogued as rs749953492; called by mutect2, varscan2
- FAM214A | c.149A>G p.Q50R | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99958654; called by muse, mutect2
- FAM83E | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs757251950, COSV54368396; called by muse, mutect2, varscan2
- FAR2 | c.1329del p.K443Nfs*4 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as COSV99479542; called by mutect2, pindel, varscan2
- FAT3 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs538781318, COSV53082222, COSV53087184, COSV53104933; called by muse, mutect2, varscan2
- FBN2 | c.6412del p.D2138Tfs*111 | Frame Shift Del (DEL) | VAF 27/106 reads (25%) | catalogued as COSV52520596; called by mutect2, pindel, varscan2
- FBRS | c.676C>T p.R226C (on ENST00000287468; = p.R746C on NM_001105079.3) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756616817, COSV54915152; called by muse, mutect2, varscan2
- FBXL18 | c.1630G>A p.V544I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV66107467; called by muse, mutect2, varscan2
- FBXW8 | c.956G>A p.R319H (on ENST00000309909; = p.R357H on NM_012174.1) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs372814319; called by muse, mutect2, varscan2
- FCGR2B | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 40/425 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV52680736; called by muse, mutect2, varscan2
- FCRL6 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs780674077, COSV58939935; called by muse, mutect2, varscan2
- FCSK | c.2743G>A p.V915M | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV55368564; called by muse, mutect2, varscan2
- FER | c.1742C>T p.T581I | Missense Mutation (SNP) | VAF 74/316 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as rs1401901866, COSV55285504; called by muse, mutect2, varscan2
- FHOD1 | c.2963G>A p.R988Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99264657; called by muse, mutect2, varscan2
- FLNC | c.7108G>A p.G2370S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.94); catalogued as rs201917318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT3LG | c.351del p.S118Afs*24 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs769482947; called by mutect2, varscan2
- FMNL1 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as rs781402859, COSV58955672; called by mutect2, varscan2
- FMNL1 | c.2759G>A p.R920H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.588); catalogued as rs755479906, COSV58955689; called by muse, mutect2, varscan2
- FN3KRP | c.608T>C p.L203P | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99485155; called by muse, mutect2
- FNBP1 | c.918A>C p.E306D | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100852864; called by muse, mutect2, varscan2
- FOXI1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.051); catalogued as rs1307118466, COSV60388250; called by muse, varscan2
- FOXI1 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.162); catalogued as rs749678694, COSV100089671; called by muse, varscan2
- FOXJ2 | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1000445085, COSV50817638; called by muse, mutect2, varscan2
- FRMD6 | c.673C>T p.R225* (on ENST00000344768 / NM_001267046.2; = p.R217* on NM_152330.4) | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100655564, COSV61089604; called by muse, mutect2, varscan2
- FSCN2 | c.1370G>A p.G457D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.181); catalogued as COSV100585667; called by muse, mutect2, varscan2
- FTMT | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as COSV58419945; called by muse, mutect2, varscan2
- FTO | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs151263395, COSV67110617, COSV67113005; called by muse, mutect2, varscan2
- FYB2 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs755007742, COSV58587299; called by muse, mutect2, varscan2
- G6PD | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as CM1111162, COSV63702529; called by muse, mutect2, varscan2
- GABBR1 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV63541510; called by muse, mutect2, varscan2
- GAD1 | c.755dup p.X252_splice | Splice Site (INS) | VAF 24/94 reads (26%) | catalogued as rs771470806; called by mutect2, pindel, varscan2
- GAREM1 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52506898; called by muse, mutect2, varscan2
- GCC2 | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV59174645; called by muse, mutect2, varscan2
- GDF15 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs745582302, COSV53250602; called by muse, mutect2
- GIT2 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs778758972, COSV58085059; called by mutect2, varscan2
- GLI4 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60681656; called by muse, mutect2, varscan2
- GNAS | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as rs903152482, COSV100008105; called by muse, mutect2
- GP6 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773642386, COSV59976624; called by muse, mutect2, varscan2
- GPATCH4 | c.940G>T p.G314* | Nonsense Mutation (SNP) | VAF 44/159 reads (28%) | catalogued as rs868665472, COSV58039259, COSV58041808; called by muse, mutect2, varscan2
- GPR158 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs371356903; called by muse, mutect2, varscan2
- GPR32 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs762217628, COSV54513645; called by muse, mutect2, varscan2
- GRIK4 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs771449360, COSV70800722; called by muse, mutect2, varscan2
- GRM1 | c.2941C>T p.R981C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV51113753; called by muse, mutect2, varscan2
- GSTM4 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 73/330 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs375686135; called by muse, mutect2, varscan2
- GTF3C1 | c.5963G>A p.R1988H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs760347646, COSV62239601, COSV62245106; called by muse, mutect2, varscan2
- GTF3C1 | c.4487T>C p.F1496S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100649844; called by muse, mutect2, varscan2
- HAO1 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs751134577, COSV101113109, COSV66491383; called by muse, mutect2, varscan2
- HAPLN1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1176234826, COSV57146023; called by muse, mutect2, varscan2
- HELZ2 | c.5956G>A p.A1986T (on ENST00000467148 / NM_001037335.2; = p.A1417T on NM_033405.3) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs375422831; called by muse, mutect2, varscan2
- HIPK1 | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs762593832, COSV61246547; called by muse, mutect2, varscan2
- HLA-DMB | c.301_302dup p.Q102Pfs*8 | Frame Shift Ins (INS) | VAF 35/190 reads (18%) | catalogued as rs750367215; called by mutect2, varscan2
- HLX | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV65044463; called by muse, mutect2, varscan2
- HMCN1 | c.16490A>G p.Q5497R | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs781229770, COSV54882762, COSV54884664; called by muse, mutect2, varscan2
- HNRNPA0 | c.914_916del p.F305del | In Frame Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs1336752399; called by mutect2, pindel, varscan2
- HOGA1 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as rs116527624, COSV56729121; ClinVar: uncertain significance; called by muse, varscan2
- HOXB1 | c.862A>G p.T288A | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV53316679; called by muse, mutect2, varscan2
- HOXC4 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57698313; called by muse, mutect2, varscan2
- HOXC6 | c.626dup p.G210Rfs*63 | Frame Shift Ins (INS) | VAF 18/74 reads (24%) | catalogued as rs765056816; called by mutect2, pindel, varscan2
- HPD | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs762065329, COSV56641348; called by muse, mutect2, varscan2
- HSP90B1 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs368251601; called by muse, mutect2, varscan2
- HSPA2 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.109); catalogued as COSV99905001, COSV99905211; called by muse, mutect2, varscan2
- HSPB11 | c.338C>G p.T113S | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.116); catalogued as COSV52040416; called by muse, mutect2, varscan2
- HTR1E | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781747051, COSV59507211; called by muse, mutect2, varscan2
- HTRA2 | c.1057G>A p.G353R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as rs755545814, COSV51206423; called by muse, mutect2, varscan2
- HUWE1 | c.7711C>T p.P2571S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53338079; called by muse, mutect2, varscan2
- HYDIN | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs552008331, COSV55492527; called by mutect2, varscan2
- HYOU1 | c.811G>T p.G271W | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68215284; called by muse, mutect2, varscan2
- IK | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.375); catalogued as rs538502414, COSV70257358; called by muse, varscan2
- IK | c.1065C>G p.D355E | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1561979301, COSV70257505; called by muse, varscan2
- IL1R1 | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV52105057; called by muse, mutect2, varscan2
- INKA2 | c.16A>G p.R6G | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100615921; called by muse, mutect2, varscan2
- INSYN2A | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs370769092; called by muse, mutect2, varscan2
- INTS11 | c.671A>G p.K224R | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.179); catalogued as rs544844033, COSV60087616; called by muse, mutect2, varscan2
- INTS6L | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV66083864; called by muse, mutect2, varscan2
- IPO5 | c.191T>C p.V64A | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV99847769; called by muse, mutect2, varscan2
- IPO9 | c.2042C>T p.T681I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV64233063; called by muse, mutect2, varscan2
- IPPK | c.476G>A p.C159Y | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55332838; called by muse, mutect2, varscan2
- IQGAP2 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs138552758; called by muse, mutect2, varscan2
- IRF2BPL | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1411508959, COSV99468595; called by muse, mutect2
- IRF8 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as rs1297028658, COSV51900918; called by muse, mutect2
- ITGAL | c.2474del p.P825Rfs*11 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as COSV100776292; called by mutect2, pindel, varscan2
- ITGB5 | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99951194; called by muse, mutect2, varscan2
- JAG2 | c.2644G>T p.G882* | Nonsense Mutation (SNP) | VAF 18/97 reads (19%) | catalogued as rs141886501, COSV59307304; called by muse, mutect2, varscan2
- JAKMIP2 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV54599493; called by muse, mutect2, varscan2
- JCAD | c.2377G>A p.A793T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV64758430; called by muse, mutect2, varscan2
- JMJD1C | c.6068A>G p.E2023G | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs766885486, COSV59512532, COSV59513457; called by muse, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | catalogued as rs1258313537; called by mutect2, pindel, varscan2
- KCNC1 | c.1229C>T p.T410M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56392419; called by muse, mutect2, varscan2
- KCNH6 | c.1997A>G p.Q666R | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59001478; called by muse, mutect2, varscan2
- KCNJ10 | c.172A>G p.T58A | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63633086; called by muse, mutect2, varscan2
- KCNK4 | c.358T>C p.C120R | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs758483618, COSV60453672; called by muse, mutect2, varscan2
- KCNT2 | c.1913C>A p.T638K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54068960; called by muse, mutect2, varscan2
- KCTD9 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55339500; called by muse, mutect2, varscan2
- KEAP1 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.089); catalogued as rs752325770, COSV50265367; called by muse, mutect2, varscan2
- KHDRBS1 | c.934dup p.A312Gfs*56 | Frame Shift Ins (INS) | VAF 11/47 reads (23%) | catalogued as rs1365545139; called by mutect2, pindel, varscan2
- KIAA0100 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs368931727; called by muse, mutect2, varscan2
- KIAA1755 | c.3260A>G p.K1087R | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs756646502, COSV54074530; called by muse, mutect2, varscan2
- KIAA1755 | c.175T>A p.C59S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV54074538; called by muse, mutect2, varscan2
- KIF5B | c.817A>G p.T273A | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56651291; called by muse, mutect2, varscan2
- KIZ | c.708G>A p.M236I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs778629258, COSV55684506; called by muse, mutect2, varscan2
- KLHL22 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as rs1189055131, COSV61020110; called by muse, mutect2, varscan2
- KLHL36 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50718262; called by muse, mutect2, varscan2
- KLK8 | c.628-1G>T p.X210_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | catalogued as COSV51591107; called by muse, mutect2, varscan2
- KMT2C | c.4929G>T p.E1643D | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51414087; called by muse, mutect2, varscan2
- KRT14 | c.200del p.G67Afs*51 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | catalogued as rs769596857; called by mutect2, pindel
- KRT20 | c.1210G>A p.V404M | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs371817674; called by muse, mutect2, varscan2
- KRT4 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 71/308 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs370759790, COSV53406267; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRT7 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs758674885, COSV57765775; called by muse, mutect2, varscan2
- LAMA1 | c.7624G>A p.V2542M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.459); catalogued as rs1432834977, COSV101058092; called by muse, mutect2
- LAMA5 | c.5341G>A p.E1781K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1359610891, COSV53354862; called by muse, mutect2, varscan2
- LARS2 | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV55525994; called by muse, mutect2, varscan2
- LCE1A | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1243330178, COSV58726648; called by muse, mutect2, varscan2
- LGALS9 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 146/544 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.723); catalogued as rs778679416, COSV56348216; called by muse, varscan2
- LGALS9C | c.98T>A p.V33D | Missense Mutation (SNP) | VAF 103/197 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60195166; called by muse, mutect2, varscan2
- LONP1 | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as rs199733142, COSV62260889; called by muse, mutect2, varscan2
- LPAR2 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as rs1402413043, COSV52554868; called by muse, mutect2, varscan2
- LRIG1 | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as COSV99834650; called by muse, mutect2, varscan2
- LRP1 | c.8009G>A p.S2670N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.419); catalogued as COSV99677886; called by muse, mutect2, varscan2
- LRP4 | c.3604C>T p.R1202C | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1460217409, COSV66134603; called by muse, mutect2, varscan2
- LRP6 | c.1133A>T p.D378V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1022328266, COSV53784542; called by muse, mutect2, varscan2
- LRRC1 | c.680T>A p.V227D | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV63828219; called by muse, mutect2, varscan2
- LRRC18 | c.448G>T p.G150W | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53282512; called by muse, mutect2, varscan2
- LRRC59 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs143077743; called by muse, mutect2, varscan2
- LRRC8D | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470893412, COSV61578030; called by muse, mutect2, varscan2
- LRRIQ3 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as rs374700532, COSV63049390; called by muse, mutect2, varscan2
- LUZP1 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1235056800, COSV56499149; called by muse, mutect2, varscan2
- LY9 | c.20A>G p.H7R | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99627692; called by muse, mutect2, varscan2
- MAB21L1 | c.734del p.G245Afs*13 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs1489102829, COSV100076702; called by mutect2, pindel, varscan2
- MACF1 | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as rs191298596, COSV58363902; called by muse, mutect2, varscan2
- MAMDC4 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as rs138838642; called by muse, mutect2, varscan2
- MAMDC4 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs574605467, COSV56032159; called by muse, mutect2, varscan2
- MAP3K4 | c.479del p.N160Mfs*8 | Frame Shift Del (DEL) | VAF 21/95 reads (22%) | catalogued as COSV62334603; called by mutect2, varscan2
- MASP1 | c.1063T>C p.W355R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370498457; called by mutect2, varscan2
- MAST3 | c.2346C>A p.S782R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.078); catalogued as COSV53218303; called by muse, mutect2, varscan2
- MAZ | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99361591; called by muse, mutect2, varscan2
- MCEMP1 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs142070554; called by muse, mutect2, varscan2
- MCM3AP | c.4499T>A p.V1500D | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52437226; called by muse, mutect2, varscan2
- MIB2 | c.282-1G>T p.X94_splice | Splice Site (SNP) | VAF 17/45 reads (38%) | catalogued as COSV61755228; called by muse, mutect2, varscan2
- MLF2 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV99180127; called by muse, mutect2, varscan2
- MMD2 | c.476G>A p.S159N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV68660046; called by muse, mutect2, varscan2
- MMP10 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV54245345; called by muse, mutect2, varscan2
- MRPS16 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs1046594668, COSV60281614; called by muse, varscan2
- MS4A12 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.153); catalogued as COSV50014577; called by muse, mutect2, varscan2
- MSLNL | c.1827del p.S610Afs*80 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | catalogued as rs763258321; called by mutect2, pindel, varscan2
- MTARC2 | c.502T>C p.F168L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.04); catalogued as COSV63765170; called by muse, mutect2, varscan2
- MTCL1 | c.3526G>A p.V1176M (on ENST00000306329 / NM_001378206.1; = p.V857M on NM_015210.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.125); catalogued as rs752932785, COSV60403325; called by mutect2, varscan2
- MTFP1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs969962190, COSV56741516; called by muse, mutect2, varscan2
- MUC17 | c.1556G>A p.S519N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.134); catalogued as rs920163822, COSV60282704; called by muse, mutect2, varscan2
- MX1 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55818283; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs764857791; called by mutect2, pindel
- MYH15 | c.5063G>A p.R1688Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as rs368123037, COSV56305952; called by muse, mutect2, varscan2
- MYH2 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs150705907, COSV55433291; called by muse, mutect2, varscan2
- MYH3 | c.1759G>A p.V587M | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs765585804, COSV56862181; called by muse, mutect2, varscan2
- MYH7 | c.5363A>C p.Q1788P | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100806896; called by mutect2, varscan2
- MYO18A | c.2999G>A p.R1000H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as rs764393653, COSV62863857; called by muse, mutect2, varscan2
- MYO18A | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs747144978, COSV62863875; called by muse, mutect2, varscan2
- MYO1D | c.2941del p.V981Wfs*56 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | catalogued as COSV57830612; called by mutect2, pindel, varscan2
- MYO7B | c.1238_1240del p.K413del | In Frame Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs1465810388; called by pindel, varscan2
- NAA80 | c.785C>A p.P262H (on ENST00000417393 / NM_001200018.2; = p.P284H on NM_012191.4) | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.436); catalogued as COSV56497006; called by muse, mutect2, varscan2
- NAALADL2 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs749574830, COSV69154228; called by muse, mutect2, varscan2
- NAT8 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.194); catalogued as COSV55542330; called by muse, mutect2, varscan2
- NAV1 | c.5593C>T p.R1865* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV55215063; called by muse, mutect2, varscan2
- NCKAP5L | c.3449C>T p.P1150L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs201610169, COSV100259365; called by muse, mutect2
- NCL | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs112363453, COSV59545203; called by muse, mutect2, varscan2
- NCOA5 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 70/280 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV51643089; called by muse, mutect2, varscan2
- NCOA6 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368096873; called by muse, mutect2, varscan2
- NCOR2 | c.3178del p.R1060Vfs*3 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | catalogued as rs749518211, COSV100656528, COSV62300840; called by mutect2, pindel, varscan2
- NDUFAF5 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as rs1224418048, COSV65246649; called by muse, mutect2, varscan2
- NEDD4L | c.2416G>T p.E806* (on ENST00000400345 / NM_001144967.3; = p.E786* on NM_015277.6) | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99897104; called by muse, mutect2, varscan2
- NEPRO | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV58723030; called by muse, mutect2, varscan2
- NFATC1 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs779010195, COSV53696757; called by muse, mutect2, varscan2
- NIBAN2 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as COSV64823891; called by muse, mutect2, varscan2
- NKRF | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as rs767690358, COSV58660967; called by muse, mutect2, varscan2
- NLRC5 | c.1346dup p.G450Wfs*105 | Frame Shift Ins (INS) | VAF 5/27 reads (19%) | catalogued as rs772651939; called by mutect2, pindel, varscan2
- NLRP4 | c.2447C>T p.A816V | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV56707233; called by muse, mutect2, varscan2
- NLRP6 | c.2050_2052del p.E684del | In Frame Del (DEL) | VAF 7/31 reads (23%) | catalogued as rs754832325; called by mutect2, pindel, varscan2
- NLRP9 | c.206G>A p.W69* | Nonsense Mutation (SNP) | VAF 58/195 reads (30%) | catalogued as COSV60460821; called by muse, mutect2, varscan2
- NOC4L | c.612del p.A205Pfs*13 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as rs1402340327; called by mutect2, pindel, varscan2
- NOC4L | c.1252T>C p.Y418H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100400305; called by muse, mutect2, varscan2
- NOD2 | c.1583del p.P528Qfs*235 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOS3 | c.2900G>A p.G967E | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV99872382; called by muse, mutect2, varscan2
- NPAS3 | c.331del p.D111Tfs*17 (on ENST00000356141 / NM_001164749.2; = p.D81Tfs*17 on NM_022123.3) | Frame Shift Del (DEL) | VAF 25/95 reads (26%) | catalogued as COSV58076957; called by mutect2, pindel, varscan2
- NPAS4 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60652129; called by muse, mutect2
- NPAT | c.3805C>T p.R1269W | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs774211463, COSV53716702; called by muse, mutect2, varscan2
- NPHP3 | c.3082C>T p.R1028C | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs781175860, COSV58628763; called by muse, mutect2, varscan2
- NPTX2 | c.761T>C p.L254P | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55716482; called by muse, mutect2, varscan2
- NR1H3 | c.257del p.K86Rfs*28 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as COSV101269783; called by mutect2, pindel, varscan2
- NRBP1 | c.581G>A p.C194Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99275382; called by muse, mutect2, varscan2
- NSUN2 | c.100T>C p.W34R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.997); catalogued as COSV99243539; called by muse, mutect2
- NT5M | c.622del p.R208Afs*34 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as rs754390000; called by mutect2, pindel
- NUDT16L1 | c.601_603del p.K201del | In Frame Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs1283990748; called by pindel, varscan2
- NYX | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1472694043, COSV61180391; called by muse, mutect2, varscan2
- OBSCN | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as rs1284747016, COSV52744540; called by muse, mutect2, varscan2
- OBSCN | c.2505G>A p.M835I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV52751264; called by muse, mutect2, varscan2
- OBSCN | c.7147C>T p.R2383W | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1239653998, COSV52751297; called by muse, mutect2, varscan2
- OGDH | c.240del p.R81Afs*19 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs777887578; called by mutect2, varscan2
- OPRD1 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52380627; called by muse, mutect2, varscan2
- OPRM1 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as rs77013544, COSV57677194; called by muse, mutect2, varscan2
- OPTN | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.341); catalogued as COSV99537849; called by muse, mutect2, varscan2
- OR1D5 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs371822460; called by muse, mutect2, varscan2
- OR8G5 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 58/244 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); catalogued as rs1303935813, COSV100422395; called by muse, varscan2
- OR9Q1 | c.871C>A p.L291M | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV59038043; called by muse, mutect2, varscan2
- ORMDL2 | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.381); catalogued as COSV54477970; called by muse, mutect2, varscan2
- OSBP | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs765435028, COSV55661339; called by muse, mutect2, varscan2
- PACS2 | c.287_289del p.F96del | In Frame Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs1425778118; called by pindel, varscan2
- PACS2 | c.290_292del p.S97del | In Frame Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs782429503; called by pindel, varscan2
- PACS2 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs782690320, COSV57650715; called by muse, mutect2, varscan2
- PACSIN1 | c.666G>T p.Q222H | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV55059064; called by muse, mutect2
- PANK4 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs1467616064, COSV65865957; called by muse, mutect2, varscan2
- PAOX | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs760508202, COSV53371503; called by muse, mutect2, varscan2
- PASK | c.3065del p.N1022Tfs*6 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs745388191; called by mutect2, varscan2
- PAXIP1 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as rs910817563, COSV68185098; called by muse, mutect2, varscan2
- PCDHA11 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV100256060; called by muse, mutect2, varscan2
- PCDHA9 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.087); catalogued as COSV65324217, COSV65330952; called by muse, mutect2, varscan2
- PCDHGB1 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV53913871; called by muse, mutect2, varscan2
- PCLO | c.7507C>G p.P2503A | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV61622115; called by muse, mutect2, varscan2
- PDE2A | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57803794; called by muse, mutect2, varscan2
- PDE7A | c.935C>T p.T312I (on ENST00000401827 / NM_001242318.3; = p.T286I on NM_002603.4) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs1230288722, COSV65152473; called by muse, mutect2
- PFKL | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as rs754434256, COSV60363327; called by muse, mutect2, varscan2
- PHKA2 | c.662A>G p.H221R | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV66052861; called by muse, mutect2, varscan2
- PIANP | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs529550863, COSV57707640; called by mutect2, varscan2
- PIK3C2G | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | catalogued as rs377755015, COSV56801017; called by muse, mutect2, varscan2
- PKP3 | c.1390del p.L464Sfs*183 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | catalogued as rs757594408; called by mutect2, pindel
- PLEKHG3 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781308900, COSV55978042; called by muse, mutect2, varscan2
- PLEKHM2 | c.3028C>T p.R1010C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs781466914, COSV53816324; called by muse, mutect2, varscan2
- PM20D1 | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1484485947, COSV65648376, COSV65649102; called by muse, mutect2, varscan2
- POLRMT | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as rs764500242, COSV73933140; called by muse, mutect2, varscan2
- POM121C | c.3233C>T p.T1078M (on ENST00000607367; = p.T836M on NM_001099415.3) | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.33); catalogued as rs781806876, COSV99993200; called by muse, mutect2, varscan2
- PPP1R26 | c.2692del p.V898Sfs*56 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as rs1365223299; called by mutect2, pindel, varscan2
- PPP3R2 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100701960; called by muse, mutect2
- PRKACG | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55243242; called by muse, mutect2, varscan2
- PRKD2 | c.1678G>T p.G560W | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52185108; called by muse, mutect2, varscan2
- PRPF4B | c.325T>G p.L109V | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV61783593; called by muse, mutect2, varscan2
- PRRC2B | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775941500, COSV61934862; called by muse, mutect2, varscan2
- PRRC2C | c.4913C>A p.P1638H (on ENST00000367742; = p.P1636H on NM_015172.4) | Missense Mutation (SNP) | VAF 11/290 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1265462406; called by muse, mutect2
- PRSS53 | c.371G>A p.S124N | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.146); catalogued as rs561799109, COSV54923347; called by muse, mutect2, varscan2
- PRXL2C | c.228G>T p.E76D | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as COSV64450046; called by muse, mutect2, varscan2
- PSAT1 | c.346A>G p.K116E | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV61302027; called by muse, mutect2, varscan2
- PSKH1 | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99345077; called by muse, mutect2, varscan2
- PSMD2 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as rs186752843; called by muse, mutect2, varscan2
- PTPRK | c.2741A>C p.N914T (on ENST00000368215 / NM_001291984.2; = p.N915T on NM_002844.4) | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV63893094; called by muse, mutect2, varscan2
- PUM3 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs142006198, COSV65896618; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3387dup p.A1130Sfs*9 | Frame Shift Ins (INS) | VAF 30/111 reads (27%) | catalogued as rs752866106; called by mutect2, varscan2
- RAD54L2 | c.3812G>A p.R1271Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs752899591, COSV56577513; called by muse, mutect2, varscan2
- RAI1 | c.1444A>C p.S482R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99885429; called by mutect2, varscan2
- RALB | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55602287; called by muse, mutect2, varscan2
- RALGAPA1 | c.1826del p.N609Ifs*2 | Frame Shift Del (DEL) | VAF 24/112 reads (21%) | catalogued as rs748033282; called by mutect2, varscan2
- RAPGEF1 | c.3218G>A p.R1073Q | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs34330901; called by muse, mutect2, varscan2
- RASGRF1 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1199183242, COSV69177307; called by muse, mutect2, varscan2
- RBBP8NL | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs369153183; called by muse, mutect2, varscan2
- RBM5 | c.1439A>G p.Y480C | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61736809; called by muse, mutect2, varscan2
- RBMS3 | c.1067G>T p.R356M (on ENST00000383767 / NM_001003793.3; = p.R338M on NM_001003792.3) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as COSV56136066; called by muse, mutect2, varscan2
- RC3H2 | c.2917A>G p.T973A | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61798892, COSV61801676; called by muse, mutect2, varscan2
- RCSD1 | c.168dup p.K57Qfs*9 | Frame Shift Ins (INS) | VAF 18/68 reads (26%) | catalogued as rs761840115; called by mutect2, varscan2
- RELN | c.7910G>A p.R2637H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV58990683; called by muse, mutect2, varscan2
- REXO1 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs760529975, COSV50075480; called by muse, mutect2, varscan2
- RFX2 | c.733A>G p.I245V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); catalogued as COSV100354051; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs751982308; called by mutect2, varscan2
- RHBDL1 | c.1199G>A p.R400Q (on ENST00000219551 / NM_001318733.2; = p.R335Q on NM_001278720.2) | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs749227263, COSV53484021; called by muse, mutect2, varscan2
- RHBDL3 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746532243, COSV52185662; called by muse, mutect2, varscan2
- RIOX2 | c.1238_1239del p.E413Vfs*20 (on ENST00000333396 / NM_001042533.2; = p.E412Vfs*20 on NM_032778.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | catalogued as rs766649364; called by pindel, varscan2
- RIOX2 | c.809A>G p.D270G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV57723887; called by muse, varscan2
- RIPOR1 | c.1261C>T p.R421C (on ENST00000379312 / NM_001193522.2; = p.R417C on NM_024519.4) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs775583803, COSV99243947; called by mutect2, varscan2
- RIPOR1 | c.2351C>T p.T784M (on ENST00000379312 / NM_001193522.2; = p.T780M on NM_024519.4) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs370307377; called by muse, mutect2, varscan2
- RMDN1 | c.680_682del p.R227del | In Frame Del (DEL) | VAF 10/89 reads (11%) | catalogued as rs771191809; called by pindel, varscan2
- RNF112 | c.1067G>A p.C356Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs762130985, COSV71327009; called by muse, mutect2, varscan2
- RNF2 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV62279041; called by muse, mutect2, varscan2
- RNF213 | c.7271G>A p.C2424Y | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765247294, COSV60392444; called by muse, mutect2, varscan2
- ROBO1 | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 30/124 reads (24%) | catalogued as rs1358072685, COSV71392523; called by muse, mutect2, varscan2
- ROR1 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs761386607, COSV64284741; called by muse, mutect2, varscan2
- ROS1 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.358); catalogued as COSV63852709; called by muse, mutect2, varscan2
- RP1L1 | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100262529; called by muse, mutect2, varscan2
- RPGRIP1 | c.2566C>T p.L856F | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as COSV52846643; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RTL1 | c.3751G>A p.G1251S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs199509151; called by muse, mutect2, varscan2
- RUSC2 | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.483); catalogued as COSV63427892; called by muse, mutect2, varscan2
- RYR3 | c.1588G>A p.G530R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370528698; called by muse, mutect2, varscan2
- SACS | c.9305del p.L3102* | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as COSV66537749; called by mutect2, varscan2
- SACS | c.2576T>C p.I859T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV66536278; called by muse, mutect2, varscan2
- SAFB2 | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs547264084, COSV53040628; called by muse, mutect2, varscan2
- SAMD4B | c.1340A>G p.Y447C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.171); catalogued as COSV58750490; called by muse, mutect2, varscan2
- SAP30BP | c.629A>C p.K210T | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53127118; called by muse, mutect2, varscan2
- SASH1 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); catalogued as COSV66559667; called by muse, varscan2
- SCN5A | c.1433G>T p.R478M | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.483); catalogued as COSV61118733; called by muse, mutect2, varscan2
- SCN7A | c.233dup p.N78Kfs*8 | Frame Shift Ins (INS) | VAF 34/179 reads (19%) | catalogued as rs764500272; called by mutect2, varscan2
- SDK1 | c.5284del p.V1762Wfs*2 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | catalogued as COSV101269709, COSV67356055, COSV67359997; called by mutect2, pindel, varscan2
- SELENOO | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755927400, COSV66598822; called by muse, mutect2, varscan2
- SELENOO | c.1531C>T p.Q511* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV99956548; called by muse, mutect2, varscan2
- SEMA4B | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs746051036, COSV60172697, COSV60175218; called by muse, mutect2, varscan2
- SEMA5A | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs149803731; called by muse, mutect2, varscan2
- SET | c.734G>A p.G245E (on ENST00000372692 / NM_001374326.1; = p.G232E on NM_003011.4) | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.182); catalogued as COSV59001395; called by muse, varscan2
- SGPP1 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 23/120 reads (19%) | catalogued as rs201466945, COSV55974766; called by muse, mutect2, varscan2
- SH2B1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1198783948, COSV100451242, COSV59461283; called by muse, mutect2, varscan2
- SH2D3A | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361769998, COSV55585082; called by muse, mutect2, varscan2
- SH3PXD2A | c.2593G>A p.V865M (on ENST00000369774 / NM_001365079.1; = p.V837M on NM_014631.2) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.649); catalogued as rs144776136; called by muse, mutect2, varscan2
- SH3RF1 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs770333018, COSV52919016; called by muse, varscan2
- SIDT2 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1331831478, COSV54055938; called by muse, mutect2, varscan2
- SIGLEC10 | c.362A>G p.E121G | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59479740; called by muse, mutect2, varscan2
- SIN3A | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV64582132; called by muse, mutect2, varscan2
- SIPA1L1 | c.1486T>C p.F496L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV62169012; called by muse, mutect2, varscan2
- SLC25A1 | c.805_807del p.K269del | In Frame Del (DEL) | VAF 9/60 reads (15%) | catalogued as rs782489989; called by pindel, varscan2
- SLC25A15 | c.906A>G p.*302Wext*32 | Nonstop Mutation (SNP) | VAF 31/91 reads (34%) | catalogued as COSV58556705; called by muse, mutect2, varscan2
- SLC26A11 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV58338791; called by muse, mutect2, varscan2
- SLC27A4 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as rs771361561, COSV55959211; called by muse, mutect2, varscan2
- SLC43A2 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1273103077, COSV56768044; called by muse, mutect2, varscan2
- SLC5A5 | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV55831804; called by muse, mutect2, varscan2
- SLC7A10 | c.471del p.T158Pfs*12 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as rs753589038, COSV53507811; called by mutect2, pindel, varscan2
- SLC9A1 | c.2341G>A p.A781T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs200843173, COSV56051983; called by muse, mutect2, varscan2
- SLC9C1 | c.2014del p.S672Hfs*9 | Frame Shift Del (DEL) | VAF 39/170 reads (23%) | catalogued as rs761139813; called by mutect2, pindel, varscan2
- SLITRK6 | c.2363C>T p.A788V | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68389614; called by muse, mutect2, varscan2
- SMAD5 | c.328T>C p.C110R | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72505671; called by muse, mutect2, varscan2
- SMC2 | c.2251del p.T751Pfs*9 | Frame Shift Del (DEL) | VAF 41/171 reads (24%) | catalogued as rs1257129093; called by mutect2, pindel, varscan2
- SMTN | c.507G>T p.E169D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.931); catalogued as COSV100295060; called by muse, mutect2, varscan2
- SNIP1 | c.1076A>G p.K359R | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.32); catalogued as rs1413120174, COSV56165871; called by muse, mutect2, varscan2
- SNRNP200 | c.2540T>C p.L847P | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100108198; called by muse, mutect2
- SNRNP48 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs992336797, COSV60938880; called by muse, mutect2, varscan2
- SNX29 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1264088142, COSV73754430; called by muse, mutect2, varscan2
- SOX10 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM119669, COSV61005099; called by muse, mutect2, varscan2
- SOX4 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55193610, COSV99782243; called by muse, mutect2, varscan2
- SPEF2 | c.3343C>T p.R1115C | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200848371, COSV61545540, COSV61549421; called by muse, mutect2, varscan2
- SPIRE2 | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs762472678, COSV65554704, COSV65557905; called by muse, mutect2, varscan2
- SPTA1 | c.2245C>A p.L749M | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.213); catalogued as rs777149969, COSV63750234; called by muse, mutect2, varscan2
- SRGAP1 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.607); catalogued as rs149964620, COSV100754744; called by muse, mutect2, varscan2
- SSRP1 | c.682A>G p.K228E | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53478484; called by muse, mutect2, varscan2
- SSU72 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs751224426, COSV52215759; called by muse, mutect2, varscan2
- ST6GAL2 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | PolyPhen benign (0.107); catalogued as COSV100868038, COSV64530025, COSV64531551; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 38/160 reads (24%) | PolyPhen possibly damaging (0.692); catalogued as rs369940675; called by muse, mutect2, varscan2
- STARD10 | c.610_612del p.S204del | In Frame Del (DEL) | VAF 15/85 reads (18%) | catalogued as rs753643170; called by pindel, varscan2
- STIMATE | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.873); catalogued as rs775254081, COSV61890620; called by muse, mutect2, varscan2
- STING1 | c.1030G>T p.G344C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as COSV58172136; called by muse, mutect2, varscan2
- STRIP2 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV50803528; called by muse, mutect2, varscan2
- STX11 | c.173T>G p.L58R | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM142008, COSV62448712; called by muse, mutect2, varscan2
- STX1A | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56094385, COSV99736455; called by muse, mutect2, varscan2
- STX5 | c.131del p.P44Qfs*2 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs746707646, COSV53677890; called by mutect2, varscan2
- SULT1C2 | c.272C>A p.P91H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as rs1272921131, COSV52264148; called by muse, mutect2, varscan2
- SUPT3H | c.655A>C p.S219R (on ENST00000371460 / NM_181356.3; = p.S208R on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV60935252; called by muse, mutect2, varscan2
- SUPT6H | c.370del p.M124Cfs*70 | Frame Shift Del (DEL) | VAF 33/114 reads (29%) | catalogued as rs1372943034; called by mutect2, varscan2
- SUSD1 | c.209A>G p.Q70R | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV62582612; called by muse, mutect2, varscan2
- SVIL | c.3686T>C p.I1229T (on ENST00000355867 / NM_021738.3; = p.I803T on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV100881645; called by muse, mutect2, varscan2
- SVIL | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1359983977, COSV63442660; called by muse, mutect2
- SYNE3 | c.1166A>G p.E389G | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100516709; called by muse, mutect2, varscan2
- SYNGAP1 | c.3962del p.P1321Qfs*68 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | catalogued as rs753212727; called by mutect2, varscan2
- SYT2 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs765719765, COSV66141426; called by muse, mutect2, varscan2
- TACC3 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV57603393; called by muse, mutect2, varscan2
- TAF1 | c.1274C>T p.A425V (on ENST00000373790 / NM_138923.4; = p.A446V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.573); catalogued as rs766246603, COSV52107055; called by muse, mutect2, varscan2
- TANC2 | c.4556del p.P1519Lfs*33 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as COSV101267456, COSV67333336; called by mutect2, pindel, varscan2
- TARBP2 | c.1042C>T p.R348C (on ENST00000266987 / NM_134323.2; = p.R327C on NM_004178.4) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs747821228, COSV57199213; called by muse, mutect2, varscan2
- TATDN2 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs761917837, COSV55050937; called by muse, mutect2, varscan2
- TBC1D17 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs756728908, COSV55577561; called by muse, mutect2, varscan2
- TBC1D22A | c.460+2T>C p.X154_splice | Splice Site (SNP) | VAF 8/39 reads (21%) | catalogued as COSV61436598; called by muse, mutect2, varscan2
- TBX5 | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs200382742, COSV59859131; ClinVar: benign; called by muse, mutect2, varscan2
- TCP1 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs370832633; called by muse, mutect2, varscan2
- TECRL | c.730+1G>A p.X244_splice | Splice Site (SNP) | VAF 36/116 reads (31%) | catalogued as rs369606261; called by muse, mutect2, varscan2
- TECTA | c.1853C>T p.T618M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs779314752, COSV99882048; called by mutect2, varscan2
- TENM1 | c.4733C>T p.A1578V | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as rs1257951880, COSV64427190; called by muse, mutect2, varscan2
- TEX15 | c.1214T>C p.I405T (on ENST00000256246; = p.I788T on NM_001350162.2) | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV56343224; called by muse, mutect2, varscan2
- THAP6 | c.295A>G p.R99G | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.025); catalogued as COSV61161904; called by muse, varscan2
- THBS3 | c.1274C>A p.P425H | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV64248715; called by muse, mutect2, varscan2
- THBS3 | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV57426010; called by muse, mutect2, varscan2
- TIAM2 | c.4511G>A p.R1504H (on ENST00000529824; = p.R1475H on NM_012454.3) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.405); catalogued as COSV51638566; called by muse, varscan2
- TICAM1 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs146110283; called by muse, mutect2, varscan2
- TIMELESS | c.13A>G p.M5V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.914); catalogued as COSV99974497; called by muse, mutect2
- TKTL2 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54917900; called by muse, mutect2, varscan2
- TLE2 | c.1612dup p.R538Pfs*59 | Frame Shift Ins (INS) | VAF 6/35 reads (17%) | catalogued as rs756800910; called by mutect2, pindel, varscan2
- TLR9 | c.1690G>A p.V564M | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.066); catalogued as rs200059070, COSV62345865; called by muse, mutect2, varscan2
- TMC3 | c.1921C>T p.R641* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as rs116898002; called by muse, mutect2, varscan2
- TMC6 | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs774998109, COSV59808279; called by muse, mutect2, varscan2
- TMC7 | c.2113C>T p.R705C | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs1185596722, COSV58582133; called by muse, mutect2, varscan2
- TMCC1 | c.1739C>T p.A580V (on ENST00000393238 / NM_001349268.2; = p.A256V on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV61439121; called by muse, mutect2, varscan2
- TMEM116 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759014592, COSV61391255; called by muse, mutect2, varscan2
- TMEM176B | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV58438948; called by muse, mutect2, varscan2
- TMEM242 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.293); catalogued as rs868955517, COSV65653985; called by muse, mutect2, varscan2
- TMEM59 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.863); catalogued as COSV99329448; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs749773249; called by mutect2, varscan2
- TMEM94 | c.657del p.F220Sfs*31 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as rs753764149; called by mutect2, pindel, varscan2
- TMEM94 | c.2443A>G p.M815V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1279543384, COSV58593599; called by muse, mutect2, varscan2
- TMF1 | c.3155A>G p.Y1052C | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV68373748; called by muse, mutect2, varscan2
- TNKS2 | c.2269C>T p.R757* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as rs747817039, COSV65414951; called by muse, mutect2, varscan2
- TNXB | c.7720G>A p.E2574K (on ENST00000647633; = p.E2327K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); catalogued as rs764604500, COSV64475307; called by muse, mutect2, varscan2
- TOM1L2 | c.538A>G p.R180G (on ENST00000379504 / NM_001350333.2; = p.R130G on NM_001033551.3) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1270944554, COSV58884242, COSV58884704; called by muse, mutect2, varscan2
- TP53BP2 | c.403G>T p.A135S (on ENST00000343537 / NM_001031685.3; = p.A6S on NM_005426.2) | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (1); PolyPhen probably damaging (0.985); catalogued as COSV100636636, COSV59067022; called by muse, varscan2
- TPH1 | c.1174A>G p.T392A | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as COSV51457342; called by muse, mutect2, varscan2
- TRABD | c.707T>C p.L236P | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57712834; called by muse, mutect2, varscan2
- TRAM1L1 | c.947T>A p.I316N | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV60291446, COSV60292856; called by muse, mutect2, varscan2
- TRANK1 | c.6410G>A p.R2137Q | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1473163087, COSV57144062; called by muse, mutect2, varscan2
- TRAPPC9 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1182738290, COSV66893466; called by muse, mutect2, varscan2
- TRIM17 | c.821del p.P274Qfs*17 | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | catalogued as rs758372115; called by mutect2, varscan2
- TRIM29 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs375996169, COSV100531595; called by muse, mutect2, varscan2
- TRIM42 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs1410061100, COSV53880795; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1859del p.K620Sfs*9 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as rs1174386062; called by mutect2, pindel, varscan2
- TRIM9 | c.1895C>T p.S632L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.487); catalogued as COSV53614153; called by muse, mutect2, varscan2
- TRPC3 | c.631T>C p.C211R (on ENST00000379645 / NM_001366479.2; = p.C138R on NM_003305.2) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as COSV99313724; called by muse, mutect2
- TRPS1 | c.1660C>T p.H554Y (on ENST00000220888 / NM_001330599.2; = p.H567Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV55230331; called by muse, mutect2, varscan2
- TRPV3 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs746084220, COSV56789420; called by muse, mutect2, varscan2
- TSHR | c.1858A>G p.T620A | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV99993114; called by muse, mutect2
- TSHZ2 | c.2454del p.M819* | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as COSV100295175, COSV100295449; called by mutect2, pindel, varscan2
- TSPAN10 | c.456del p.L154Cfs*19 (on ENST00000574882 / NM_001290212.1; = p.L116Cfs*19 on NM_031945.4) | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs771262491, COSV100148738, COSV60773593; called by mutect2, pindel, varscan2
- TSPYL4 | c.468del p.K156Nfs*23 | Frame Shift Del (DEL) | VAF 12/71 reads (17%) | catalogued as rs1178402530; called by mutect2, pindel, varscan2
- TTLL12 | c.1196A>G p.Q399R | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as COSV53354502; called by muse, mutect2, varscan2
- TTN | c.11828C>T p.A3943V (on ENST00000591111; = p.A3897V on NM_003319.4) | Missense Mutation (SNP) | VAF 40/152 reads (26%) | catalogued as rs370295357; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBGCP6 | c.1495G>A p.V499M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs867932672, COSV50536430; called by muse, mutect2, varscan2
- U2SURP | c.2598del p.K866Nfs*10 | Frame Shift Del (DEL) | VAF 63/241 reads (26%) | catalogued as COSV67533295; called by mutect2, pindel, varscan2
- UBE2E1 | c.94_96del p.K32del | In Frame Del (DEL) | VAF 16/91 reads (18%) | catalogued as rs781155886; called by pindel, varscan2
- UBR4 | c.13328G>A p.R4443H | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64384256; called by muse, mutect2, varscan2
- UBXN10 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs759257774, COSV66771902; called by muse, mutect2, varscan2
- UGT3A2 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as rs200458466, COSV56929077; called by muse, mutect2, varscan2
- UHRF2 | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52791410; called by muse, mutect2, varscan2
- UNC13A | c.4432G>A p.V1478M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.24); catalogued as COSV53190609, COSV99406926; called by muse, mutect2, varscan2
- UNC13A | c.3144G>A p.W1048* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | catalogued as COSV53190632; called by muse, mutect2, varscan2
- URB2 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs767496560, COSV50982529; called by muse, mutect2, varscan2
- USP24 | c.4655G>A p.R1552H | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.379); catalogued as rs1370911381, COSV99601342; called by muse, mutect2, varscan2
- USP49 | c.1411C>A p.L471I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51895452; called by muse, mutect2, varscan2
- VASN | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs113954688, COSV52028635; called by muse, mutect2, varscan2
- VEGFC | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs866870659, COSV54595131, COSV54596693; called by muse, mutect2, varscan2
- VN1R2 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100448252; called by muse, mutect2, varscan2
- VPS13B | c.4616T>C p.L1539P | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV62135676; called by muse, mutect2
- VRTN | c.271A>G p.S91G | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV99832529; called by muse, mutect2
- VSIG10 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs750908297, COSV63652435; called by muse, mutect2, varscan2
- WASF3 | c.1382G>T p.R461L | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as COSV58963502, COSV58966800; called by muse, mutect2, varscan2
- WASL | c.1263del p.V422Wfs*17 | Frame Shift Del (DEL) | VAF 28/146 reads (19%) | catalogued as rs1158703313; called by mutect2, pindel, varscan2
- WDCP | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs768617221, COSV54591796; called by muse, mutect2, varscan2
- WDR33 | c.3844G>A p.G1282R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.391); catalogued as rs764567706, COSV59246276; called by muse, mutect2, varscan2
- WDR90 | c.2752C>T p.R918C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as rs766480010, COSV53467257; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WSCD1 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs749910733, COSV100496899; called by mutect2, varscan2
- XPO1 | c.3029C>A p.A1010D | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.284); catalogued as COSV68945025; called by muse, mutect2, varscan2
- XPO7 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs773235175, COSV53012041; called by muse, mutect2, varscan2
- XPR1 | c.1880G>A p.R627Q | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62554926; called by muse, mutect2, varscan2
- XYLT1 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769212477, COSV54480026; called by muse, mutect2, varscan2
- YJEFN3 | c.269A>G p.Q90R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1413570054, COSV99389354; called by muse, mutect2, varscan2
- YTHDC2 | c.3952C>T p.R1318W | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs181938024, COSV50737610; called by muse, mutect2, varscan2
- ZBED4 | c.2557G>A p.A853T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs753510939, COSV53464324; called by muse, mutect2, varscan2
- ZC3H18 | c.1306C>T p.R436* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as COSV56323309; called by muse, mutect2, varscan2
- ZC3HC1 | c.685A>T p.T229S | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV61297585; called by muse, mutect2, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs781677398, COSV57709922; called by mutect2, varscan2
- ZEB1 | c.2520G>T p.Q840H | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.986); catalogued as COSV58038468, COSV58038996; called by muse, mutect2, varscan2
- ZER1 | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV52564532; called by muse, mutect2, varscan2
- ZFYVE28 | c.2545C>T p.R849C | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139636438; called by muse, mutect2, varscan2
- ZGRF1 | c.4105C>T p.R1369C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.204); catalogued as rs746118376, COSV71392959; called by muse, mutect2, varscan2
- ZNF20 | c.721A>G p.T241A | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.214); catalogued as rs776857588, COSV61998843; called by muse, mutect2, varscan2
- ZNF287 | c.382A>G p.T128A | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV67688205; called by muse, mutect2, varscan2
- ZNF358 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1377559017, COSV51175579; called by muse, mutect2
- ZNF443 | c.622del p.W208Gfs*34 | Frame Shift Del (DEL) | VAF 29/114 reads (25%) | catalogued as rs748113623; called by mutect2, pindel, varscan2
- ZNF454 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs766675892, COSV60767312; called by muse, mutect2, varscan2
- ZNF536 | c.1734G>A p.M578I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1400504740, COSV62820361; called by muse, mutect2, varscan2
- ZNF567 | c.994_997del p.T332Gfs*16 (on ENST00000536254 / NM_001322913.1; = p.T301Gfs*16 on NM_152603.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | catalogued as COSV62444553; called by mutect2, pindel, varscan2
- ZNF627 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs372586505; called by muse, mutect2, varscan2
- ZNF671 | c.1104_1105del p.Y369Sfs*10 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs781267140; called by pindel, varscan2
- ZNF761 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as rs760993579, COSV61887818; called by muse, mutect2, varscan2
- ZNF804A | c.635T>A p.I212N | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV100170841; called by muse, mutect2, varscan2
- ZNF83 | c.1385G>A p.C462Y | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56528813; called by muse, mutect2, varscan2
- ZNF835 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs746857795, COSV73379431, COSV73379818; called by mutect2, varscan2
- ZNF836 | c.2617C>T p.R873W | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.972); catalogued as rs750525227, COSV59081627; called by muse, mutect2, varscan2
- ABL1 | c.1950del p.L651Wfs*43 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel
- ADAMTSL3 | c.1428_1429del p.F477* | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | called by mutect2, pindel, varscan2
- AHDC1 | c.3135del p.F1046Sfs*96 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- ARAF | c.23del p.P8Lfs*26 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | called by mutect2, pindel, varscan2
- ATP10D | c.2588del p.L863* | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- BAZ1A | c.1318dup p.E440Gfs*4 | Frame Shift Ins (INS) | VAF 21/109 reads (19%) | called by mutect2, pindel, varscan2
- BCL9 | c.92del p.P31Lfs*3 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, pindel, varscan2
- CA14 | c.360del p.S121Qfs*27 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- CCAR2 | c.1513del p.L505* | Frame Shift Del (DEL) | VAF 25/108 reads (23%) | called by mutect2, pindel, varscan2
- CDC25B | c.1569del p.G524Afs*22 (on ENST00000245960 / NM_021873.3; = p.G510Afs*22 on NM_004358.4) | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- CDH10 | c.1920del p.E641Sfs*3 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- CEP350 | c.8251dup p.I2751Nfs*29 | Frame Shift Ins (INS) | VAF 52/235 reads (22%) | called by mutect2, pindel, varscan2
- CEP85L | c.663del p.K221Nfs*32 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | called by mutect2, pindel, varscan2
- CFAP43 | c.2374del p.S792Afs*19 | Frame Shift Del (DEL) | VAF 57/260 reads (22%) | called by mutect2, pindel, varscan2
- CIC | c.1553del p.P518Rfs*5 | Frame Shift Del (DEL) | VAF 21/97 reads (22%) | called by mutect2, pindel, varscan2
- CLASP2 | c.4379C>A p.A1460D (on ENST00000359576; = p.A1459D on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNTN4 | c.1511del p.P504Lfs*18 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | called by mutect2, pindel, varscan2
- COL18A1 | c.1874del p.G625Efs*10 (on ENST00000359759 / NM_130444.3; = p.G390Efs*10 on NM_030582.4) | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel
- CUBN | c.1556dup p.R520Pfs*17 | Frame Shift Ins (INS) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- CUL9 | c.6258_6259del p.C2087Lfs*7 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by pindel, varscan2
- CXCL9 | c.323del p.K108Rfs*4 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | called by mutect2, pindel, varscan2
- DCST2 | c.1982_1984del p.E661del | In Frame Del (DEL) | VAF 9/39 reads (23%) | called by pindel, varscan2
- DHX36 | c.2113dup p.M705Nfs*20 | Frame Shift Ins (INS) | VAF 30/103 reads (29%) | called by mutect2, pindel, varscan2
- DMXL2 | c.5084del p.F1695Sfs*15 | Frame Shift Del (DEL) | VAF 19/81 reads (23%) | called by mutect2, pindel, varscan2
- DNAH2 | c.11973_11974del p.L3992Tfs*2 | Frame Shift Del (DEL) | VAF 17/81 reads (21%) | called by pindel, varscan2
- DNTTIP2 | c.1896dup p.R633Tfs*24 | Frame Shift Ins (INS) | VAF 35/159 reads (22%) | called by mutect2, pindel
- DOP1A | c.3016del p.T1006Lfs*39 | Frame Shift Del (DEL) | VAF 22/104 reads (21%) | called by mutect2, pindel, varscan2
- ERBIN | c.3830dup p.Q1278Sfs*10 (on ENST00000284037 / NM_001253697.2; = p.Q1237Sfs*10 on NM_018695.4) | Frame Shift Ins (INS) | VAF 39/197 reads (20%) | called by mutect2, pindel, varscan2
- FAT3 | c.5828dup p.N1943Kfs*14 | Frame Shift Ins (INS) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- FOXN2 | c.1123dup p.I375Nfs*3 | Frame Shift Ins (INS) | VAF 16/87 reads (18%) | called by mutect2, pindel, varscan2
- GALNT7 | c.473del p.L158Wfs*25 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- GDF5 | c.157del p.L53Wfs*34 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- GEMIN2 | c.653T>C p.L218S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- GIGYF1 | c.809del p.G270Efs*75 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- GNAZ | c.612del p.Q205Rfs*29 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | called by mutect2, pindel, varscan2
- HACE1 | c.2282del p.L761Yfs*33 | Frame Shift Del (DEL) | VAF 21/101 reads (21%) | called by mutect2, pindel, varscan2
- HDHD2 | c.534dup p.K179Efs*17 | Frame Shift Ins (INS) | VAF 17/91 reads (19%) | called by mutect2, pindel, varscan2
- HIF1A | c.112dup p.Y38Lfs*2 | Frame Shift Ins (INS) | VAF 18/78 reads (23%) | called by mutect2, pindel, varscan2
- HNRNPUL2 | c.2052_2053del p.G686Lfs*3 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by pindel, varscan2
- IGSF9B | c.2280del p.D761Tfs*22 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, varscan2
- IL1RAPL2 | c.1170dup p.G391Wfs*3 | Frame Shift Ins (INS) | VAF 40/97 reads (41%) | called by mutect2, pindel, varscan2
- IL7R | c.361del p.I121* | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- INTS5 | c.2401del p.A801Hfs*4 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | called by mutect2, varscan2
- ITM2A | c.323dup p.L109Pfs*5 | Frame Shift Ins (INS) | VAF 27/90 reads (30%) | called by pindel, varscan2
- KCNH7 | c.305del p.N102Mfs*11 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | called by mutect2, pindel, varscan2
- KDM6B | c.3300del p.K1101Rfs*3 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- KIAA0895L | c.45del p.S16Afs*13 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- KIF22 | c.1583del p.K528Rfs*4 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel, varscan2
- KIF7 | c.3778del p.R1260Afs*16 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- KIF7 | c.1702del p.L568Wfs*31 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | called by mutect2, pindel, varscan2
- KIR2DL1 | c.147T>A p.C49* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- KMT2C | c.6875del p.P2292Hfs*13 | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | called by mutect2, pindel, varscan2
- KNL1 | c.6802_6803del p.L2268Ifs*3 (on ENST00000346991 / NM_170589.5; = p.L2242Ifs*3 on NM_144508.5) | Frame Shift Del (DEL) | VAF 26/144 reads (18%) | called by pindel, varscan2
- LAMA5 | c.9720del p.P3242Rfs*47 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- LEPROTL1 | c.124dup p.Y42Lfs*17 | Frame Shift Ins (INS) | VAF 30/146 reads (21%) | called by mutect2, varscan2
- LONRF3 | c.504dup p.V169Rfs*11 | Frame Shift Ins (INS) | VAF 33/85 reads (39%) | called by mutect2, pindel, varscan2
- LRBA | c.6031del p.T2011Qfs*11 | Frame Shift Del (DEL) | VAF 17/109 reads (16%) | called by mutect2, pindel, varscan2
- MARCKS | c.939del p.S314Hfs*55 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- MBP | c.86del p.K29Rfs*36 | Frame Shift Del (DEL) | VAF 38/178 reads (21%) | called by mutect2, pindel, varscan2
- MRC2 | c.3656del p.G1219Afs*5 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, pindel
- MROH2B | c.3685del p.D1229Tfs*15 | Frame Shift Del (DEL) | VAF 23/111 reads (21%) | called by mutect2, pindel, varscan2
- MVK | c.417del p.A141Rfs*18 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- MYCN | c.127A>G p.T43A | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- MZF1 | c.2058_2059del p.C686Wfs*70 | Frame Shift Del (DEL) | VAF 9/55 reads (16%) | called by pindel, varscan2
- NAXD | c.1020dup p.S341Lfs*39 | Frame Shift Ins (INS) | VAF 10/65 reads (15%) | called by mutect2, pindel, varscan2
- NBR1 | c.1560dup p.G521Wfs*2 | Frame Shift Ins (INS) | VAF 26/122 reads (21%) | called by mutect2, pindel, varscan2
- NF1 | c.2835dup p.D946* | Frame Shift Ins (INS) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.7455del p.S2486Rfs*103 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- NPAT | c.1642del p.S548Vfs*11 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- PAPPA | c.3016dup p.T1006Nfs*4 | Frame Shift Ins (INS) | VAF 15/68 reads (22%) | called by mutect2, pindel, varscan2
- PARP1 | c.1076dup p.E360Rfs*29 | Frame Shift Ins (INS) | VAF 10/52 reads (19%) | called by mutect2, pindel
297 further variants in this file (44 protein-altering or splice-affecting, 235 silent, 18 other) are not listed here.
